Somatic mutation profile of tumor specimen TCGA-55-6642-01A (aliquot TCGA-55-6642-01A-11D-1855-08) from TCGA case TCGA-55-6642, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.3 years (23,107 days).
Specimen TCGA-55-6642-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32c34928-e19c-4f50-989b-ba32f2f946bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6642-11A (Solid Tissue Normal), aliquot TCGA-55-6642-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1005879f-0532-4dac-9b6c-7abeb335c778

The open-access MAF lists 133 somatic variants for this specimen: 99 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 4, RNA 1, 3'Flank 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCC11 | c.1500del p.N500Kfs*8 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as COSV62323344, COSV62325603; called by mutect2, pindel, varscan2
- ADAMTS13 | c.4004C>G p.A1335G | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV99390250, COSV99390432; called by muse, mutect2
- ADAMTS18 | c.1802G>T p.C601F | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51424419; called by muse, mutect2, varscan2
- ADAMTS2 | c.2891C>A p.P964H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397447; called by muse, mutect2, varscan2
- ATM | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV53728632; called by muse, mutect2, varscan2
- ATM | c.8083G>T p.G2695C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555127166, COSV53741150, COSV53763120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN1 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774318148, COSV55233743; called by muse, mutect2, varscan2
- BOLL | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99986832, COSV99987029; called by muse, mutect2, varscan2
- BOLL | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs761048419, COSV56577389, COSV99987033; called by muse, mutect2, varscan2
- C3orf14 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs780990044, COSV51707817; called by muse, mutect2, varscan2
- C7 | c.1853G>C p.R618P | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV100495553, COSV57477481, COSV57482578; called by muse, mutect2, varscan2
- CAMSAP1 | c.3499G>T p.D1167Y | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV56729421; called by muse, mutect2, varscan2
- CCKBR | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV58106694; called by muse, mutect2, varscan2
- CEP83 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs769005960, COSV60411833; called by muse, mutect2, varscan2
- CHRNB2 | c.943A>T p.S315C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63809639; called by muse, mutect2, varscan2
- CNGA3 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374258471, CM014536, COSV55626007, COSV55629033; called by muse, mutect2, varscan2
- CRY1 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); catalogued as rs751659487, COSV50493027; called by muse, mutect2
- CSMD2 | c.5090T>A p.L1697Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53972833; called by muse, mutect2, varscan2
- CYP24A1 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53777196; called by muse, mutect2, varscan2
- DCLRE1A | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV63749879; called by muse, mutect2
- DNAH5 | c.12038G>C p.R4013P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV54210025, COSV54257625; called by muse, mutect2
- DNAH7 | c.11410G>T p.V3804L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV56790553; called by mutect2, varscan2
- EPHA7 | c.2630G>T p.R877L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV65178391, COSV65183780, COSV65193538; called by muse, mutect2, varscan2
- GABRA2 | c.1131T>A p.N377K | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as rs200515415; called by muse, mutect2, varscan2
- GABRA5 | c.551C>A p.A184E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.092); catalogued as COSV59479333, COSV59486857; called by muse, mutect2, varscan2
- GAL3ST4 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs1177832681, COSV57588556; called by muse, mutect2, varscan2
- GATA5 | c.1186T>A p.L396M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53347739; called by muse, mutect2, varscan2
- GGN | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as COSV53059399; called by mutect2, varscan2
- GLP2R | c.1493A>G p.N498S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52330350; called by muse, mutect2
- GPR142 | c.1232T>A p.F411Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59520672; called by muse, mutect2, varscan2
- GPX8 | c.311T>A p.L104* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV57053812, COSV57058246; called by muse, mutect2, varscan2
- H3C8 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV59953904; called by muse, mutect2, varscan2
- IGFLR1 | c.215del p.P72Rfs*26 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as COSV99495222; called by mutect2, pindel, varscan2
- IGHV3-13 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1555437302; called by muse, mutect2, varscan2
- ITLN1 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV58277180; called by muse, mutect2, varscan2
- KAT6B | c.5831A>G p.Y1944C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143966521; called by muse, mutect2, varscan2
- KCNQ2 | c.1514A>T p.Q505L (on ENST00000359125 / NM_172107.4; = p.Q477L on NM_004518.6) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV60555782; called by muse, mutect2, varscan2
- KIF3C | c.2360C>A p.A787E | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as COSV53102639; called by muse, mutect2, varscan2
- LAMA1 | c.7764G>T p.L2588F | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV67545499; called by muse, mutect2, varscan2
- LCE3E | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV64232374; called by muse, mutect2
- LPCAT4 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV59219706; called by muse, mutect2, varscan2
- LRP5 | c.3142A>G p.I1048V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV53724874; called by muse, mutect2, varscan2
- LRRN3 | c.1999C>G p.Q667E | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV57824814; called by muse, mutect2, varscan2
- MAN1A2 | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV62982169; called by muse, mutect2, varscan2
- MPV17 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99274336; called by muse, mutect2
- MS4A6A | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV60618902, COSV60622383; called by muse, mutect2, varscan2
- MTNR1A | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100208237, COSV56156921; called by muse, mutect2
- ODF2 | c.259C>T p.H87Y (on ENST00000434106 / NM_153433.2; = p.H63Y on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV63549325; called by muse, mutect2, varscan2
- OR10G2 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as COSV73390487; called by muse, mutect2, varscan2
- OR4C46 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as rs1233021940, COSV60219138; called by muse, varscan2
- OR51B5 | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV56177490; called by muse, mutect2, varscan2
- OR5K1 | c.477T>A p.H159Q | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV60305554; called by muse, mutect2, varscan2
- PCDHB2 | c.2033C>A p.A678E | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV50579315, COSV99165043; called by muse, mutect2, varscan2
- PDE6A | c.999-1G>C p.X333_splice | Splice Site (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99678260; called by muse, varscan2
- PKD2L1 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as rs773088402, COSV58395927; called by muse, mutect2, varscan2
- PLXNA4 | c.3991G>T p.D1331Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58165773; called by muse, mutect2, varscan2
- POLR3D | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100120081; called by muse, mutect2, varscan2
- PREX1 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV64257665; called by muse, mutect2, varscan2
- RAB20 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99940883; called by muse, mutect2, varscan2
- RABEP1 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52589318; called by muse, mutect2, varscan2
- RPS6KC1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65303319; called by muse, mutect2, varscan2
- RYR1 | c.5453C>G p.A1818G | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- RYR2 | c.10448C>A p.P3483H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63720090; called by muse, mutect2, varscan2
- SELPLG | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV99947376; called by muse, mutect2, varscan2
- SLC32A1 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54148197, COSV54148683; called by muse, mutect2, varscan2
- SLC4A10 | c.2540A>T p.K847M (on ENST00000446997 / NM_001354461.2; = p.K817M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55803690; called by mutect2, varscan2
- SLITRK2 | c.2054A>T p.Y685F | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV59429642; called by muse, mutect2, varscan2
- SOWAHB | c.1223G>T p.S408I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV57555736; called by muse, mutect2, varscan2
- SP100 | c.974-2A>T p.X325_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as COSV51020158; called by muse, mutect2, varscan2
- SPATA31D1 | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100782746; called by muse, mutect2, varscan2
- SPEF2 | c.3163A>G p.T1055A | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs771393710, COSV61554435; called by muse, mutect2, varscan2
- SSR4 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (1); PolyPhen possibly damaging (0.458); catalogued as COSV54210573; called by muse, mutect2, varscan2
- STK32C | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53846985; called by muse, mutect2, varscan2
- STPG2 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54790918, COSV54825054; called by muse, mutect2
- STX12 | c.629A>C p.H210P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100881294; called by muse, mutect2
- SYNGR1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.518); catalogued as rs200512399, COSV53369474; called by muse, mutect2, varscan2
- SYT16 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs1475710083, COSV70860426; called by muse, mutect2, varscan2
- SYT6 | c.1365-1G>T p.X455_splice (on ENST00000610222 / NM_001366225.1; = p.X370_splice on NM_205848.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV65772258, COSV65774843, COSV65776573; called by muse, mutect2, varscan2
- TENM4 | c.3592C>T p.Q1198* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53678813; called by muse, mutect2, varscan2
- TEP1 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 21/159 reads (13%) | catalogued as COSV53001787; called by muse, mutect2, varscan2
- TMC6 | c.1313G>C p.W438S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV59812089; called by muse, mutect2
- TMEM177 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.888); catalogued as COSV99733601; called by muse, mutect2, varscan2
- TNN | c.2663C>A p.P888H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53437694; called by muse, varscan2
- TOGARAM1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs373580836, COSV61888736; called by muse, mutect2, varscan2
- TRMT13 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV61584263; called by muse, mutect2, varscan2
- TTC37 | c.832T>G p.L278V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs777188692, COSV62453694, COSV62457244; called by muse, mutect2, varscan2
- USP33 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62471855; called by muse, mutect2, varscan2
- VANGL1 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as COSV59622973; called by muse, mutect2, varscan2
- WDR90 | c.5004G>T p.Q1668H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99553291; called by muse, mutect2, varscan2
- WDR90 | c.5004+1G>T p.X1668_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99553297; called by muse, mutect2, varscan2
- ZC3H12C | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.366); catalogued as COSV53713650; called by muse, mutect2, varscan2
- ZNF160 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV62001307; called by muse, mutect2, varscan2
- ZNF547 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs904537475, COSV99987893; called by muse, mutect2, varscan2
- ZNF630 | c.1117A>C p.K373Q | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV52098501; called by muse, mutect2, varscan2
- HOXA5 | c.523del p.Q175Rfs*11 | Frame Shift Del (DEL) | VAF 31/281 reads (11%) | called by mutect2, pindel, varscan2
- IGHV6-1 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MID1IP1 | c.482_483del p.L161Hfs*9 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PEG3 | c.2268del p.Y757Mfs*26 | Frame Shift Del (DEL) | VAF 34/226 reads (15%) | called by mutect2, pindel, varscan2
- AGL | c.1560C>T p.F520= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs778983440, COSV54059969; called by muse, varscan2
- CADM3 | c.1083C>A p.T361= (on ENST00000368125 / NM_001127173.3; = p.T395= on NM_021189.5) | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV63674961; called by muse, varscan2
- CD19 | c.1074C>T p.T358= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV61190002; called by muse, mutect2, varscan2
- CYP2S1 | c.468G>T p.L156= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV59507555; called by muse, mutect2, varscan2
- DHRS7C | c.40C>T p.L14= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1241949034, COSV57653135; called by mutect2, varscan2
- ESRRG | c.411G>T p.G137= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV63151184; called by muse, mutect2, varscan2
- FMO4 | c.1029C>T p.S343= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs1406493261, COSV63002067; called by muse, mutect2
- HTR1E | c.597G>T p.L199= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV59508195, COSV59511756; called by muse, mutect2, varscan2
- ITFG2 | c.1104C>T p.C368= | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as COSV57391405; called by muse, mutect2
- LRTM2 | c.861G>A p.P287= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs745751625, COSV99765580; called by muse, mutect2, varscan2
- NLRP10 | c.1332C>A p.A444= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV60783222; called by muse, mutect2, varscan2
- NPAP1 | c.3468G>T p.P1156= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV61506979, COSV61512314; called by muse, mutect2, varscan2
- OR10A3 | c.666G>T p.L222= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV62460433; called by muse, mutect2, varscan2
- OR51E2 | c.498C>G p.A166= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV101211337; called by muse, mutect2, varscan2
- PCDHGA3 | c.1710C>T p.D570= | Silent (SNP) | VAF 33/230 reads (14%) | catalogued as rs745630768, COSV54051044, COSV99532453; called by muse, mutect2, varscan2
- POLR3A | c.2964C>T p.G988= | Silent (SNP) | VAF 60/185 reads (32%) | catalogued as COSV64932314; called by muse, mutect2, varscan2
- POTEA | c.924A>T p.T308= (on ENST00000519951 / NM_001005365.2; = p.T262= on NM_001002920.1) | Silent (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- PTPRK | c.3138G>T p.T1046= (on ENST00000368215 / NM_001291984.2; = p.T1047= on NM_002844.4) | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV63909158; called by muse, mutect2, varscan2
- RESF1 | c.2013A>G p.E671= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV57026462; called by muse, mutect2, varscan2
- SETD5 | c.1593G>A p.R531= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs1458505101, COSV56718288; called by muse, mutect2, varscan2
- SLAMF8 | c.66T>C p.G22= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs761918847, COSV56990138; called by mutect2, varscan2
- SSBP2 | c.981G>T p.L327= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV57805677; called by muse, mutect2, varscan2
- STX12 | c.627C>T p.I209= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV64250312; called by muse, mutect2
- TAS1R2 | c.1575C>T p.F525= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV64747800; called by muse, mutect2, varscan2
- TNR | c.240C>A p.S80= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV54886098, COSV54918285; called by muse, mutect2, varscan2
- TXNIP | c.81G>T p.V27= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV65221685; called by muse, mutect2, varscan2
- USH2A | c.10449G>A p.G3483= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs751663815, COSV56451115; called by mutect2, varscan2
- WDR33 | c.1143G>T p.L381= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV59256508; called by muse, mutect2, varscan2
- ZIM3 | c.693C>A p.A231= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as COSV54147381; called by muse, mutect2, varscan2
- ZNF462 | c.6402G>T p.P2134= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV52953028; called by muse, mutect2, varscan2
- ZNF547 | c.48G>T p.V16= | Silent (SNP) | VAF 31/278 reads (11%) | catalogued as COSV99987891; called by muse, mutect2, varscan2
- CACNA1A | c.5547-1230G>A | Intron (SNP) | VAF 23/55 reads (42%) | catalogued as rs1246077018, COSV100800227, COSV64214551; called by muse, mutect2, varscan2
- MIR1915 | chr10:21495845 G>T | 3'Flank (SNP) | VAF 8/16 reads (50%) | catalogued as COSV65795456; called by muse, mutect2
- SSPOP | n.8966G>T | RNA (SNP) | VAF 7/57 reads (12%) | catalogued as rs763693478, COSV65132883, COSV65139067; called by muse, mutect2, varscan2
